Somatic mutation profile of tumor specimen TCGA-06-0125-02A (aliquot TCGA-06-0125-02A-11D-2280-08) from TCGA case TCGA-06-0125, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.9 years (23,343 days).
Specimen TCGA-06-0125-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54ac8e1e-3c09-4882-8a3e-43807599064f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0125-10A (Blood Derived Normal), aliquot TCGA-06-0125-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94b019d9-8165-4c00-a5db-8cbc5f8bd4d2

The open-access MAF lists 89 somatic variants for this specimen: 74 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 13, Frame Shift Del 8, Nonsense Mutation 3, In Frame Ins 2, Splice Region 2, Splice Site 2, RNA 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2307/2521 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs794728708, CM010421, COSV63694898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV59388871; called by muse, mutect2, varscan2
- ATP6V0A4 | c.640-1G>C p.X214_splice | Splice Site (SNP) | VAF 31/104 reads (30%) | catalogued as COSV59477418; called by muse, mutect2, varscan2
- BRS3 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV65711160; called by muse, mutect2, varscan2
- CACNA1D | c.1538G>A p.R513H (on ENST00000350061 / NM_001128840.3; = p.R533H on NM_000720.4) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1559570791, COSV55452065; called by muse, mutect2, varscan2
- CDYL2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs145890469; called by muse, mutect2, varscan2
- CHAT | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs200176236, COSV60319829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNNM2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV63995722; called by muse, varscan2
- COL3A1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs200446048; called by muse, mutect2, varscan2
- DOCK5 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs776922979, COSV52405321; called by muse, mutect2, varscan2
- DST | c.12215C>G p.S4072C (on ENST00000361203 / NM_001374722.1; = p.S1660C on NM_015548.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55023756; called by muse, mutect2, varscan2
- DTD1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs745796443, COSV66280343; called by muse, mutect2, varscan2
- ECEL1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV58813095; called by muse, mutect2, varscan2
- EMILIN1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs760975435, COSV53154989, COSV53155566; called by muse, mutect2, varscan2
- ESX1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 126/484 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV65424685; called by muse, mutect2, varscan2
- FAM47A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1426442027, COSV60494190; called by muse, mutect2, varscan2
- FER1L6 | c.4966C>T p.R1656C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771879378, COSV67547743; called by muse, mutect2, varscan2
- FLT3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV54059336; called by muse, mutect2, varscan2
- FZD9 | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60670663; called by muse, mutect2, varscan2
- GLRA3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV56864812; called by muse, mutect2, varscan2
- GPKOW | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50243573; called by muse, mutect2, varscan2
- GPR132 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs757850974, COSV61678126; called by muse, mutect2, varscan2
- GPR65 | c.811A>T p.M271L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50863237; called by muse, mutect2, varscan2
- KCTD16 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs868542964, COSV72579641; called by muse, mutect2, varscan2
- KDR | c.2107del p.D703Ifs*6 | Frame Shift Del (DEL) | VAF 37/144 reads (26%) | catalogued as COSV55771303; called by mutect2, pindel, varscan2
- KRT74 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59772334; called by muse, mutect2, varscan2
- MAGEB6 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 92/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66872546; called by muse, mutect2, varscan2
- MARK4 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1033007935, COSV53465457; called by muse, mutect2, varscan2
- MELTF | c.1332G>A p.P444= | Splice Region (SNP) | VAF 19/84 reads (23%) | catalogued as rs774892741, COSV56382700, COSV99586056; called by muse, mutect2, varscan2
- MKRN1 | c.811T>A p.F271I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55437574; called by muse, mutect2, varscan2
- MUC16 | c.4498T>C p.S1500P | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as COSV67476699; called by muse, mutect2, varscan2
- MYH11 | c.2655G>A p.L885= | Splice Region (SNP) | VAF 55/174 reads (32%) | catalogued as rs760141485, COSV55558843; called by muse, mutect2, varscan2
- NDRG4 | c.128-1G>C p.X43_splice (on ENST00000570248 / NM_001378344.1; = p.X75_splice on NM_020465.4 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 109/304 reads (36%) | catalogued as COSV50748834; called by muse, mutect2, varscan2
- NPBWR2 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); catalogued as rs371922929; called by muse, mutect2, varscan2
- OR2Z1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782631146; called by muse, mutect2, varscan2
- OR51F1 | c.918A>T p.K306N | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV58578735; called by muse, mutect2
- P2RY13 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV56385060; called by muse, mutect2, varscan2
- PLEKHG1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100651618; called by muse, mutect2, varscan2
- PLEKHG4B | c.1466G>A p.R489H (on ENST00000283426; = p.R845H on NM_052909.5) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs529537081, COSV52049819; called by muse, mutect2, varscan2
- PRR23B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.896); catalogued as COSV61494189; called by muse, mutect2, varscan2
- PTCH1 | c.4180C>T p.R1394* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as rs1297685477, COSV59465625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | catalogued as rs146650273; called by pindel, varscan2
- PWWP3B | c.1603A>C p.M535L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61800471; called by muse, mutect2, varscan2
- SERPINA7 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); catalogued as COSV59664805, COSV59665125; called by muse, mutect2, varscan2
- SIGLEC8 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as rs141833256; called by muse, mutect2, varscan2
- SLC17A7 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs150211751; called by muse, mutect2, varscan2
- TCL1B | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61551811; called by muse, mutect2, varscan2
- TEAD1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV57566780; called by muse, mutect2, varscan2
- TGM4 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as rs754139975, COSV56094811; called by muse, mutect2, varscan2
- TYSND1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.259); catalogued as COSV54643376; called by muse, mutect2, varscan2
- UGT3A2 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.59); catalogued as rs138640717; called by muse, mutect2, varscan2
- XKR7 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs371180407; called by muse, mutect2, varscan2
- ZNF274 | c.1351C>T p.R451C (on ENST00000610905; = p.R346C on NM_016324.3) | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs777288675, COSV58762764; called by muse, mutect2, varscan2
- ZNF653 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs768514644, COSV53403741; called by muse, mutect2, varscan2
- ZNF829 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs918219907, COSV66986634; called by muse, mutect2, varscan2
- ABCG8 | c.1032_1035del p.L345Qfs*5 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- ASCC3 | c.4430C>A p.S1477* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- C16orf70 | c.436del p.A146Lfs*23 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | called by mutect2, pindel, varscan2
- CAMKMT | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC115 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSC3 | c.217_227del p.V73Wfs*13 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- FAM47C | c.3025G>T p.D1009Y | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- IL10RA | c.444del p.K149Rfs*37 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- INF2 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOP9 | c.509_510insAGA p.E169dup | In Frame Ins (INS) | VAF 23/108 reads (21%) | called by pindel, varscan2*
- PCNA | c.331_334del p.V111Qfs*5 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- PPIL4 | c.822C>A p.D274E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM15 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF213 | c.2024A>G p.Y675C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SSR3 | c.252_260dup p.H86_K87insNKH | In Frame Ins (INS) | VAF 20/59 reads (34%) | called by mutect2, varscan2
- UGT1A3 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- USE1 | c.206del p.K69Rfs*9 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ZMYM3 | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK2 | c.1014G>A p.S338= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs777140241, COSV60920423; called by muse, mutect2, varscan2
- ARSD | c.1353G>A p.S451= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs749735838, COSV54200862; called by muse, mutect2, varscan2
- C8orf58 | c.243C>T p.A81= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs752279989, COSV51515701; called by muse, mutect2, varscan2
- CD248 | c.414C>T p.G138= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs375088730; called by muse, mutect2, varscan2
- CEP97 | c.2142G>A p.L714= | Silent (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- FBLN2 | c.3327G>A p.A1109= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs746614248, COSV55486933; called by muse, mutect2, varscan2
- GNGT2 | c.18C>T p.S6= | Silent (SNP) | VAF 75/244 reads (31%) | catalogued as rs758509109, COSV55930112; called by muse, mutect2, varscan2
- MID1 | c.534T>C p.H178= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as COSV58191485, COSV58196292; called by muse, mutect2, varscan2
- OLAH | c.69T>G p.P23= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV65493696; called by muse, mutect2, varscan2
- OR5W2 | c.285T>C p.Y95= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV60615005, COSV60616842; called by muse, mutect2, varscan2
- PAFAH2 | c.225G>A p.L75= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV65339760; called by muse, mutect2, varscan2
- SLC8A2 | c.711G>A p.P237= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV52640768; called by muse, mutect2, varscan2
- SRPK2 | c.1473A>G p.R491= | Silent (SNP) | VAF 65/228 reads (29%) | catalogued as COSV61960050; called by muse, mutect2, varscan2
- MIR34A | n.56_59del | RNA (DEL) | VAF 96/439 reads (22%) | called by mutect2, pindel, varscan2
- Y_RNA | chr14:50083934 C>T | 5'Flank (SNP) | VAF 8/28 reads (29%) | catalogued as rs756371556; called by muse, mutect2, varscan2
